Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4967, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4967-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

TCGA-BP-4967

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right renal tumor.

Specimens Submitted:

1: SP: Kidney, and adrenal, a portion of, right, nephrectomy

2: SP: Lymph nodes, paracaval, excision

3: SP: Adrenal, right, completion adrenalectomy

DIAGNOSIS:

1. SP: Kidney, and adrenal, a portion of, right, nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 5.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

(as a circumscribed nodule that is suspicious, but not definitive, for a tumor embolus filling a vascular space)

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Multiple cortical scars, benign cortical cysts, and 2 tubulopapillary adenomas

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. SP: Lymph nodes, paracaval, excision

Lymph Nodes:

Not involved

[page 2 of 3]
Number of nodes examined:5

3. SP: Adrenal, right, completion adrenalectomy [REDACTED]:
Benign adrenal gland.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh labeled "Right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 776 g in total. The overall dimensions of the specimen are 25 x 10 x 7.5 cm. The kidney measures 12.5 x 6.5 x 6 cm. The attached ureter measures 10.5 cm in length and 0.6 cm in diameter. The attached renal vein measures 2.5 cm in length and 0.7 cm in diameter. The renal vessels and ureteral margins are grossly unremarkable. A remnant of the adrenal gland is identified, measuring 4 x 1.5 x 0.2 cm. The kidney is inked black and bivalved to reveal a subcortical, well-circumscribed, oval, bright orange to yellow hemorrhagic tumor measuring 5.5 x 4.5 x 3.7 cm. The tumor extends from the mid to lower pole of the kidney, impinges on the renal pelvis and sinus fat and is located 2.7 cm from the renal vein margin. There appears to be a layer of fat separating the tumor from the renal vein and renal pelvis. Sections through the remainder of the kidney reveal two uniloculated cystic areas lined by unremarkable kidney parenchyma. The first is identified in the mid to upper pole and measures 1.4 x 1.2 x 1.2 cm. The second is located in the upper pole and measures 1.1 x 1 x 1 cm. The renal pyramids show firm orange yellow areas of discoloration. There are similar areas of discoloration identified in the renal cortex measuring up to 0.6 x 0.6 cm in greatest dimension. The remainder of the kidney shows a pink brown parenchyma, with a well-defined corticomedullary junction. There are no lymph nodes identified in the perinephric fat. On complete opening of the ureter, it shows smooth white tan unremarkable mucosa. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UM -- ureteral margin
VM- vessel margins
TP-tumor and renal pelvis
TSF-- tumor with sinus fat
TV-tumor and renal vein
ADR-adrenal
HF-hilar fat
CYST-cystic area, mid to upper pole
RS-representative sections of renal pyramids
DA-discolored areas, renal cortex
DAT-discolored areas, renal cortex and adjacent tumor
C2-cyst, upper pole

2) The specimen is received in formalin, labeled "Paracaval lymph nodes". It consists of a 3.2 x 2.9 x 0.8 cm aggregate of fat and lymph nodes. The largest lymph node measures 0.7 x 0.6 x 0.3 cm. The specimen is entirely submitted for routine histology.

Summary of sections:

LN-lymph nodes

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

3) The specimen is received in formalin, labeled "Right adrenal gland". It consists of a 6.5 gram, 4.6 x 4.2 x 1.5 cm adrenal gland with attached periadrenal fat. The adrenal has an unremarkable orange yellow cortex, with a hemorrhagic appearing brown red central medulla. Representative sections are submitted.

Summary of sections:

A-representative adrenal gland

Summary of Sections:

Part 1: SP: Kidney, and adrenal, a portion of, right, nephrectomy [REDACTED]

Block	Sect. Site	PCs
2	adr	2
1	c2	1
2	cyst	2
1	da	1
1	dat	1
1	hf	1
2	rs	2
3	tp	3
3	tsf	3
2	tv	2
1	um	1
1	vm	1

Part 2: SP: Lymph nodes, paracaval, excision [REDACTED]

Block	Sect. Site	PCs
3	ln	8

Part 3: SP: Adrenal, right, completion adrenalectomy [REDACTED]

Block	Sect. Site	PCs
3	a	9

Source: NCI Genomic Data Commons file 98236ef9-559c-4bdc-99e9-02360a32d4c4 (TCGA-BP-4967.7025E70D-8E64-4AE2-9D48-9F8B92D47966.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).